Somatic mutation profile of tumor specimen TARGET-20-PASZAF-03A (aliquot TARGET-20-PASZAF-03A-01D) from TARGET case TARGET-20-PASZAF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,886 days).
Specimen TARGET-20-PASZAF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b84e8867-fd09-4144-a71f-08d30109bcbd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZAF-14A (Bone Marrow Normal), aliquot TARGET-20-PASZAF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdda8f46-6a71-41f1-aae8-90cd2655c87b

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.6079C>T p.R2027C | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs199867416; called by muse, mutect2, varscan2
- GABBR2 | c.*357G>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
